Somatic mutation profile of tumor specimen TCGA-73-4676-01A (aliquot TCGA-73-4676-01A-01D-1753-08) from TCGA case TCGA-73-4676, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.8 years (16,746 days).
Specimen TCGA-73-4676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2cfacbc-a824-4568-89db-6aca0d06af74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4676-11A (Solid Tissue Normal), aliquot TCGA-73-4676-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7910d9c-92e7-4992-b68f-6a35a93ff6b7

The open-access MAF lists 103 somatic variants for this specimen: 78 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 23, Nonsense Mutation 7, Frame Shift Del 3, Splice Region 2, Splice Site 1, Intron 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 31/50 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3291T>A p.H1097Q (on ENST00000272895 / NM_173076.3; = p.H779Q on NM_015657.3) | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV55948649; called by muse, mutect2, varscan2
- ACAN | c.7483A>G p.R2495G (on ENST00000560601 / NM_001369268.1; = p.R2457G on NM_013227.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61355412; called by muse, mutect2, varscan2
- ADGRG4 | c.4654T>A p.C1552S | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368223288, COSV54948825; called by muse, mutect2, varscan2
- ANK2 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52144581; called by muse, mutect2, varscan2
- ARHGAP24 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67836273; called by muse, mutect2, varscan2
- CALCOCO2 | c.1195A>G p.I399V | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV51950929; called by muse, mutect2, varscan2
- CD1C | c.855C>A p.S285R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1261175172; called by muse, mutect2
- CEP162 | c.3159A>T p.K1053N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57617250; called by muse, mutect2, varscan2
- CHD9 | c.8477A>T p.D2826V (on ENST00000398510 / NM_001382353.1; = p.D2810V on NM_025134.7) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54607439; called by muse, mutect2, varscan2
- CIART | c.852A>T p.L284F | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV51743070, COSV99290281; called by muse, mutect2, varscan2
- CNTLN | c.2884A>T p.T962S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV52065320; called by muse, mutect2, varscan2
- CSMD3 | c.7025G>T p.G2342V (on ENST00000297405 / NM_001363185.1; = p.G2238V on NM_052900.3) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52217402, COSV99828279; called by muse, mutect2, varscan2
- CSMD3 | c.7024G>A p.G2342R (on ENST00000297405 / NM_001363185.1; = p.G2238R on NM_052900.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52204955; called by muse, mutect2, varscan2
- CUL2 | c.1371G>C p.M457I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66078226, COSV66078960; called by muse, mutect2, varscan2
- DENND5A | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60231191; called by muse, mutect2, varscan2
- DNAJC6 | c.648T>A p.C216* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV54773858, COSV99674307; called by muse, mutect2, varscan2
- DNAJC6 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99674313; called by muse, mutect2, varscan2
- DRD2 | c.352T>C p.C118R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60753993; called by muse, mutect2, varscan2
- ESRP1 | c.1233G>C p.Q411H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64407634; called by muse, mutect2, varscan2
- FGFR2 | c.450_452del p.N150del | In Frame Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs752218106; called by pindel, varscan2
- FIBP | c.799G>T p.G267* (on ENST00000338369 / NM_198897.2; = p.G260* on NM_004214.5) | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100327228; called by muse, mutect2, varscan2
- GABBR2 | c.2138C>T p.T713I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); catalogued as COSV52292526; called by muse, mutect2, varscan2
- GRIN2C | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53109487; called by muse, mutect2, varscan2
- GSDMC | c.902A>G p.H301R | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52692979; called by muse, mutect2, varscan2
- HMX3 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs766586446, COSV100774131; called by muse, mutect2, varscan2
- HTR3B | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52742568; called by muse, mutect2, varscan2
- IGKV2D-29 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101534369; called by muse, mutect2, varscan2
- ITSN2 | c.4473G>A p.T1491= | Splice Region (SNP) | VAF 24/87 reads (28%) | catalogued as rs768842538, COSV61943528; called by muse, mutect2, varscan2
- KCNMB4 | c.391A>G p.M131V | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV50690685; called by muse, mutect2, varscan2
- LCE1B | c.289A>G p.S97G | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs759570259, COSV100780262; called by muse, mutect2, varscan2
- MAL | c.262-2A>G p.X88_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | catalogued as COSV59430684; called by muse, mutect2, varscan2
- MCOLN3 | c.1319A>C p.K440T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62013008; called by muse, mutect2, varscan2
- MDGA2 | c.924A>T p.T308= (on ENST00000399232 / NM_001113498.2; = p.T10= on NM_182830.4) | Splice Region (SNP) | VAF 18/29 reads (62%) | catalogued as COSV62078429; called by muse, mutect2, varscan2
- NCAPH2 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as COSV52686456; called by muse, mutect2, varscan2
- NFIA | c.1085A>T p.H362L | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.607); catalogued as COSV63607549; called by muse, mutect2
- NPY1R | c.384T>G p.I128M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56713224, COSV99648810; called by muse, mutect2, varscan2
- NUDT7 | c.539C>G p.P180R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV99215984; called by muse, mutect2, varscan2
- OR5B2 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV56907437; called by muse, mutect2, varscan2
- OR7G3 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV59639826; called by muse, mutect2, varscan2
- PGBD1 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV52551236; called by muse, mutect2, varscan2
- PLEKHG4B | c.779T>C p.V260A (on ENST00000283426; = p.V616A on NM_052909.5) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV52043130; called by muse, mutect2, varscan2
- PLG | c.2041G>T p.V681L | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV57512443; called by muse, mutect2, varscan2
- PPP3CA | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV59919229; called by muse, mutect2, varscan2
- PRKCE | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60311984; called by muse, mutect2, varscan2
- PTK2B | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs771681042, COSV57749548; called by muse, mutect2, varscan2
- RALGAPA1 | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 43/71 reads (61%) | catalogued as COSV51875594; called by muse, mutect2, varscan2
- RBM12B | c.1417A>T p.R473* | Nonsense Mutation (SNP) | VAF 107/292 reads (37%) | catalogued as COSV67897261; called by muse, mutect2, varscan2
- REG1B | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV59304282; called by muse, mutect2, varscan2
- RIMS3 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV101013317; called by muse, mutect2
- RYR2 | c.5966C>A p.P1989Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV63659326; called by muse, mutect2, varscan2
- RYR2 | c.6229G>A p.D2077N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.113); catalogued as COSV63659335; called by muse, mutect2, varscan2
- SAGE1 | c.1396A>T p.N466Y | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV61011490; called by muse, mutect2, varscan2
- SCG2 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV59538920; called by muse, mutect2, varscan2
- SEPTIN6 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59712440; called by muse, mutect2, varscan2
- SETD2 | c.4474C>T p.R1492* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV57428762; called by muse, mutect2, varscan2
- SLITRK4 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as COSV62021954; called by muse, mutect2, varscan2
- SMARCA2 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61804489; called by muse, mutect2, varscan2
- SPEF2 | c.1377G>T p.M459I | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV56794644; called by muse, mutect2, varscan2
- STOX1 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100057685, COSV53812728; called by muse, mutect2, varscan2
- SYNE2 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV59939027; called by muse, mutect2, varscan2
- SYPL2 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV63994665; called by muse, mutect2, varscan2
- TCTE1 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65255013; called by muse, mutect2, varscan2
- TFIP11 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV53225413; called by muse, mutect2, varscan2
- TMEM79 | c.63C>G p.S21R | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV55293064; called by muse, mutect2, varscan2
- TRIM60 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV61969722, COSV61971371; called by muse, mutect2, varscan2
- TTBK2 | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as COSV51157237; called by muse, mutect2, varscan2
- UBIAD1 | c.283C>A p.H95N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100954815; called by muse, mutect2, varscan2
- UBR4 | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as rs939268662, COSV64382519; called by muse, mutect2, varscan2
- VPS9D1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.683); catalogued as rs1260089891, COSV66993867; called by muse, mutect2, varscan2
- XPNPEP2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778659869, COSV64367754; called by muse, mutect2
- ZHX2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.27); catalogued as COSV58710076, COSV58715804; called by muse, mutect2, varscan2
- DACT1 | c.2413_2414delinsA p.P805Tfs*26 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | called by pindel, varscan2*
- NF1 | c.7262del p.N2421Tfs*11 (on ENST00000358273 / NM_001042492.3; = p.N2400Tfs*11 on NM_000267.3) | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.4111del p.T1371Rfs*18 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- PPIAL4A | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF20 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 97/172 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD21 | c.645_646del p.Y215* | Nonsense Mutation (DEL) | VAF 36/131 reads (27%) | called by pindel, varscan2
- ARHGEF11 | c.540G>A p.Q180= | Silent (SNP) | VAF 136/280 reads (49%) | catalogued as COSV63810209; called by muse, mutect2, varscan2
- B4GAT1 | c.1237C>A p.R413= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV60819629; called by muse, mutect2, varscan2
- BCAN | c.2568C>A p.I856= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as COSV100227935; called by muse, mutect2, varscan2
- BCAN | c.2569C>A p.R857= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as COSV100227937, COSV100228178; called by muse, mutect2, varscan2
- DMD | c.1566A>G p.G522= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV55852464; called by muse, mutect2, varscan2
- ERICH3 | c.4059C>T p.A1353= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as rs535685168, COSV58598514, COSV58598675; called by muse, mutect2, varscan2
- FEZF1 | c.1029G>A p.P343= | Silent (SNP) | VAF 56/196 reads (29%) | catalogued as rs1432400355, COSV58658143; called by muse, mutect2, varscan2
- FREM1 | c.1230T>C p.D410= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs1220767726, COSV63087132; called by muse, mutect2, varscan2
- KIAA1549 | c.4650A>G p.V1550= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs750634364, COSV54304923; called by muse, mutect2
- LAMA5 | c.3378G>T p.V1126= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99438649; called by muse, mutect2, varscan2
- MXRA5 | c.4491C>T p.S1497= | Silent (SNP) | VAF 53/86 reads (62%) | catalogued as COSV54223092; called by muse, mutect2, varscan2
- OR2T34 | c.588C>T p.D196= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as rs373688678, COSV60900244; called by muse, mutect2, varscan2
- OR6S1 | c.831G>T p.V277= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV57837497; called by muse, mutect2, varscan2
- OR9Q1 | c.477G>T p.R159= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs1381982585, COSV59036378; called by muse, mutect2, varscan2
- PAPPA2 | c.4341A>G p.T1447= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs746625723, COSV62790281, COSV62806561; called by muse, mutect2, varscan2
- PRND | c.66T>C p.S22= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99999431; called by muse, mutect2, varscan2
- PURG | c.129G>A p.A43= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV53295826; called by muse, mutect2, varscan2
- SMARCE1 | c.891C>T p.R297= | Silent (SNP) | VAF 89/144 reads (62%) | catalogued as COSV52860513; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2502A>G p.P834= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as COSV51509806; called by muse, mutect2, varscan2
- TRPV5 | c.2134T>C p.L712= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV54682881; called by muse, mutect2, varscan2
- UHRF1BP1 | c.564C>T p.L188= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as COSV51952477; called by muse, varscan2
- USP40 | c.3291G>A p.G1097= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV52476812; called by muse, mutect2, varscan2
- ZP4 | c.156T>A p.P52= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV63910786; called by muse, mutect2, varscan2
- MON2 | chr12:62603028 G>C | 3'Flank (SNP) | VAF 5/14 reads (36%) | catalogued as rs556238766; called by muse, mutect2, varscan2
- MSANTD3 | c.418+2853C>T | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100614485; called by muse, mutect2, varscan2
